Somatic mutation profile of tumor specimen ALCH-B48L-TTP1-A (aliquot ALCH-B48L-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B48L, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 63.5 years (23,190 days).
Specimen ALCH-B48L-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59d8b0f9-5305-44d3-b16e-f2274260a095.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B48L-NB2-A (Blood Derived Normal), aliquot ALCH-B48L-NB2-A-2-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7f6a213-af0f-461a-96fc-911bb82cf6f3

The open-access MAF lists 62 somatic variants for this specimen: 40 protein-altering or splice-affecting, 19 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 19, In Frame Del 3, Intron 2, Splice Region 1, Nonsense Mutation 1, 3'UTR 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 193/504 reads (38%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel, varscan2
- PTEN | c.625G>T p.G209* | Nonsense Mutation (SNP) | VAF 25/120 reads (21%) | catalogued as rs765433422, COSV64294737, COSV99057830; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC100868.1 | c.1189G>A p.E397K | Missense Mutation (SNP) | VAF 17/439 reads (4%) | SIFT tolerated (0.87); PolyPhen benign (0.015); catalogued as COSV51845029; called by muse, mutect2
- ADAM15 | c.713G>T p.R238L | Missense Mutation (SNP) | VAF 56/347 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV55126345; called by muse, mutect2, varscan2
- ARID1A | c.6746C>T p.S2249L | Missense Mutation (SNP) | VAF 7/161 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.366); catalogued as COSV61376855, COSV61377034; called by muse, mutect2
- CNOT1 | c.5797T>C p.Y1933H | Missense Mutation (SNP) | VAF 155/566 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1359951225; called by muse, mutect2, varscan2
- GDF2 | c.508G>A p.V170M | Missense Mutation (SNP) | VAF 34/315 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs201972913; called by muse, mutect2, varscan2
- IL4R | c.113A>G p.Y38C | Missense Mutation (SNP) | VAF 16/279 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99405040; called by muse, mutect2
- MICAL2 | c.4256G>A p.G1419E | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.554); catalogued as rs1416685135; called by muse, mutect2, varscan2
- OR10R2 | c.863C>G p.S288C | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.967); catalogued as COSV63769440; called by muse, mutect2
- PCDH8 | c.2460C>G p.D820E | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as COSV58813366; called by muse, mutect2, varscan2
- PKM | c.1240G>A p.V414M | Missense Mutation (SNP) | VAF 81/406 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.051); catalogued as COSV58788079; called by muse, mutect2, varscan2
- PRR14 | c.386G>A p.R129Q | Missense Mutation (SNP) | VAF 22/176 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.003); catalogued as rs759038103; called by muse, mutect2, varscan2
- RFX7 | c.2075C>T p.S692F (on ENST00000559447 / NM_001368074.1; = p.S789F on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.691); catalogued as COSV57965731; called by muse, mutect2, varscan2
- STK11IP | c.496C>T p.L166F | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.905); catalogued as rs1488233052; called by muse, mutect2, varscan2
- TTN | c.17881G>A p.G5961S (on ENST00000591111; = p.G5034S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | PolyPhen probably damaging (0.999); catalogued as rs397517488, COSV60391499; ClinVar: uncertain significance; called by mutect2, varscan2
- ANO5 | c.1628T>C p.M543T | Missense Mutation (SNP) | VAF 18/213 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AP1G1 | c.1588_1599del p.I530_L533del | In Frame Del (DEL) | VAF 42/411 reads (10%) | called by mutect2, pindel
- BRD7 | c.1706dup p.P570Sfs*18 | Frame Shift Ins (INS) | VAF 17/114 reads (15%) | called by mutect2, pindel, varscan2
- C20orf203 | c.505T>A p.S169T | Missense Mutation (SNP) | VAF 94/339 reads (28%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- CBLL2 | c.970T>A p.S324T | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.37); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- CENPN | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 12/295 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CHRNG | c.506+7_506+22del | Splice Region (DEL) | VAF 26/226 reads (12%) | called by mutect2, pindel
- FASTK | c.1220A>T p.E407V | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- IGF2R | c.4180A>G p.I1394V | Missense Mutation (SNP) | VAF 11/214 reads (5%) | SIFT tolerated (0.8); PolyPhen benign (0.001); called by muse, mutect2
- IL6ST | c.1549G>A p.A517T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.03); called by muse, mutect2
- LYST | c.2611C>G p.L871V | Missense Mutation (SNP) | VAF 61/726 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- MKRN3 | c.689C>T p.T230I | Missense Mutation (SNP) | VAF 26/329 reads (8%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2
- NRP2 | c.1666G>A p.D556N | Missense Mutation (SNP) | VAF 16/468 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- OVCH1 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 30/198 reads (15%) | SIFT tolerated (0.4); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- PHF20L1 | c.2971T>G p.L991V | Missense Mutation (SNP) | VAF 24/628 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- PLD5 | c.172A>G p.K58E | Missense Mutation (SNP) | VAF 78/277 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- RFX7 | c.1145C>T p.S382F (on ENST00000559447 / NM_001368074.1; = p.S479F on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); called by muse, mutect2
- RFX7 | c.884C>T p.P295L (on ENST00000559447 / NM_001368074.1; = p.P392L on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/184 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- SCN2A | c.3027G>T p.R1009S | Missense Mutation (SNP) | VAF 26/307 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); called by muse, mutect2
- SEPSECS | c.155A>G p.E52G | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.668); called by muse, mutect2
- SLC22A25 | c.1587_1592del p.D529_V530del | In Frame Del (DEL) | VAF 20/148 reads (14%) | called by mutect2, pindel, varscan2
- SMARCA2 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 12/271 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- SMCHD1 | c.3904C>T p.L1302F | Missense Mutation (SNP) | VAF 7/87 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.563); called by muse, mutect2
- TP53 | c.576_583del p.Q192Hfs*14 | Frame Shift Del (DEL) | VAF 172/405 reads (42%) | called by mutect2, pindel, varscan2
- ATP4A | c.597C>A p.G199= | Silent (SNP) | VAF 22/213 reads (10%) | catalogued as rs199859429, COSV52865597; called by muse, mutect2
- BRCA2 | c.6150A>G p.V2050= | Silent (SNP) | VAF 23/66 reads (35%) | called by muse, mutect2, varscan2
- CPLX2 | c.288G>A p.R96= | Silent (SNP) | VAF 23/178 reads (13%) | called by muse, mutect2, varscan2
- FANCG | c.205T>C p.L69= | Silent (SNP) | VAF 90/489 reads (18%) | called by muse, varscan2
- FKBP1C | c.321G>A p.L107= | Silent (SNP) | VAF 66/288 reads (23%) | called by muse, mutect2, varscan2
- FLNB | c.3612G>A p.L1204= | Silent (SNP) | VAF 37/133 reads (28%) | called by muse, mutect2, varscan2
- ITPR1 | c.5982G>A p.K1994= (on ENST00000354582; = p.K1939= on NM_002222.7) | Silent (SNP) | VAF 59/334 reads (18%) | called by muse, mutect2, varscan2
- LCTL | c.1302A>C p.G434= | Silent (SNP) | VAF 10/38 reads (26%) | called by muse, varscan2
- LRRC55 | c.870C>T p.S290= | Silent (SNP) | VAF 38/288 reads (13%) | called by muse, varscan2
- NOL6 | c.2520C>A p.A840= | Silent (SNP) | VAF 8/65 reads (12%) | called by muse, mutect2, varscan2
- PGPEP1L | c.123C>T p.I41= | Silent (SNP) | VAF 15/163 reads (9%) | called by muse, mutect2, varscan2
- PRPF4B | c.1023A>G p.S341= | Silent (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- RFX7 | c.1320C>G p.V440= (on ENST00000559447 / NM_001368074.1; = p.V537= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/468 reads (7%) | called by muse, mutect2
- RFX7 | c.1146C>T p.S382= (on ENST00000559447 / NM_001368074.1; = p.S479= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 29/384 reads (8%) | called by muse, mutect2
- SGSM1 | c.1866C>A p.I622= | Silent (SNP) | VAF 20/150 reads (13%) | called by muse, mutect2, varscan2
- SLIT3 | c.3900C>T p.G1300= | Silent (SNP) | VAF 18/245 reads (7%) | catalogued as rs140984258; called by muse, mutect2
- TIMELESS | c.1848G>A p.L616= | Silent (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- TUBB4A | c.741C>T p.N247= | Silent (SNP) | VAF 40/406 reads (10%) | catalogued as rs201693075, COSV51152285; ClinVar: likely benign; called by muse, mutect2
- VWA1 | c.747C>T p.P249= | Silent (SNP) | VAF 36/176 reads (20%) | called by muse, mutect2, varscan2
- B9D1 | c.404+201G>A | Intron (SNP) | VAF 26/262 reads (10%) | catalogued as rs745951509; called by muse, mutect2
- LRRC55 | c.*50C>T | 3'UTR (SNP) | VAF 52/285 reads (18%) | called by muse, varscan2
- ZMYND8 | c.26-8572C>T | Intron (SNP) | VAF 41/251 reads (16%) | catalogued as rs1485929668; called by muse, mutect2, varscan2
